Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0AT, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0AT-01A (Primary Tumor).

TSS Patient ID

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: Infiltrative ductal carcinoma

Date of Procurement: Anatomic Site: **Right Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **Frozen**

Container: **cryomold** Type of Procurement: **Radical mastectomy** Grade: **3**

T Stage: **2** N Stage: **0** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

*ICD-0-3
carcinoma, infiltrating duct, NOS 8500/3
site: breast, NOS C50.9 lw
10/20/11*

Source: NCI Genomic Data Commons file 15eb3cf1-ecf8-4d56-a3cb-04e499f575d7 (TCGA-AN-A0AT.3E8F2012-A457-4358-9C8B-23292374A743.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).